Gene-level copy-number profile of tumor specimen TCGA-DK-AA6L-01A from TCGA case TCGA-DK-AA6L, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Dome of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 48.3 years (17,635 days).
Specimen TCGA-DK-AA6L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.0c4f1475-b9ff-4f2f-9104-af22586534f1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DK-AA6L-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d97921bd-d6cc-4fdf-a681-8b2eb19a351d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 3,179; copy number 2: 13,986; copy number 3: 23,051; copy number 4: 9,840; copy number 5: 4,561; copy number 6: 3,178; copy number 7: 1,152; copy number 8: 341; copy number 9: 52; copy number 10: 346; copy number 11: 93; copy number 12: 33.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DK-AA6L-01A-11D-A390-01): tumor purity 0.64, ploidy 3.22, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,017 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:107,505,203–121,580,524, 371 genes, copy number 7 (broad region; genes not listed).
- chr2:212,999,691–213,152,427, 1 gene, copy number 8 (within-gene range 1–8): IKZF2.
- chr3:103,240,987–104,503,266, 6 genes, copy number 8: NDUFA4P2, MIR548AB, AC046144.1, TUBBP11, RAP1BP2, AC091804.1.
- chr3:115,802,363–117,139,389, 1 gene, copy number 11 (within-gene range 6–11): LSAMP.
- chr3:116,360,024–121,886,526, 92 genes, copy number 11 (broad region; genes not listed).
- chr3:123,067,025–123,992,178, 14 genes, copy number 10: PDIA5, MIR7110, SEC22A, AC112503.2, ADCY5, AC112503.1, HACD2, MYLK-AS1, MYLK, MYLK-AS2, AC020634.2, AC020634.1, CCDC14, ROPN1.
- chr3:145,824,257–167,066,320, 318 genes, copy number 7–9 (broad region; genes not listed).
- chr3:168,666,559–179,789,401, 166 genes, copy number 7–12 (broad region; genes not listed).
- chr3:179,804,063–179,804,366, 1 gene, copy number 10: AC007687.1.
- chr3:181,813,401–198,222,513, 391 genes, copy number 8–10 (broad region; genes not listed).
- chr4:115,628,812–117,691,188, 25 genes, copy number 7 (within-gene range 2–7): RPF2P2, PGAM4P2, KRT18P21, AC027613.1, EIF3KP3, TTC39CP1, MTRNR2L13, MIR1973, TRMT112P1, CUL4AP1, AC106892.1, ACTN4P1, AC093765.5, AC093765.4, AC093765.3, AC093765.2, RNU6-119P, AC093765.1, TRAM1L1, AC107399.1, LINC02262, LINC02263, LINC01378, RPSAP35, NT5C3AP1.
- chr5:58,198–2,967,955, 86 genes, copy number 7 (broad region; genes not listed).
- chr5:5,390,096–17,443,619, 197 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr8:33,338,867–33,600,023, 13 genes, copy number 7: RNU6-528P, AC067838.1, FUT10, AC091144.2, TTI2, MAK16, SNORD13, AC091144.1, SNORA70, RPL10P18, RNF122, RN7SL621P, DUSP26.
- chr8:33,641,581–33,641,939, 1 gene, copy number 7: BUD31P1.
- chr8:35,862,123–38,063,791, 44 genes, copy number 7–8 (within-gene range 4–8): AC124290.1, AC124290.2, AC124290.3, MTCYBP19, MTND6P19, MTND5P41, AP006245.1, RNU6-533P, AP006245.2, AC090809.1, RPL23P10, RNA5SP264, KCNU1, AC124076.1, TPT1P8, AC090453.1, AC092818.1, SMARCE1P4, AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1.
- chr8:40,519,565–42,171,673, 34 genes, copy number 7–12: AC010857.1, ZMAT4, AC048387.1, RNU6-356P, SFRP1, MIR548AO, RPS29P2, AC104393.1, RNU6-895P, SNORD65B, AC016868.1, GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4, GPAT4, AC009630.3, NKX6-3, ANK1, MIR486-1, MIR486-2, AC113133.1, Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2.
- chr16:63,314,264–63,618,046, 1 gene, copy number 7 (within-gene range 4–7): AC138305.1.
- chr16:63,397,707–66,335,138, 22 genes, copy number 7–8: AC138305.3, AC018846.1, LINC02165, AC092337.1, AC093536.2, AC012322.1, AC093536.1, AC092131.1, PPIAP48, AC009101.1, CDH11, AC010533.1, LINC02126, AC009055.2, AC009055.1, LINC00922, AC092138.2, AC092138.1, AC022164.1, AC025281.1, RNA5SP428, AC012325.1.
- chr18:33,851,100–35,143,470, 11 genes, copy number 7 (within-gene range 5–7): NOL4, Y_RNA, AC104985.3, AC104985.1, AC104985.2, DTNA, AC013290.1, AC022601.1, AC068506.1, MAPRE2, AC015967.2.
- chr18:35,841,759–37,236,242, 20 genes, copy number 7: NRBF2P1, MIR187, MIR3929, AC118757.1, AC091060.1, C18orf21, RPRD1A, SLC39A6, ELP2, AC023043.1, MOCOS, AC023043.4, AC023043.2, AC023043.3, FHOD3, AC055840.1, TPGS2, KIAA1328, AC016493.1, AC015961.1.
- chr18:37,243,776–37,306,333, 3 genes, copy number 7: AC015961.2, AC090386.1, AC090386.2.
- chr19:57,746,815–58,605,223, 82 genes, copy number 8 (broad region; genes not listed).
- chr21:45,593,654–46,132,848, 17 genes, copy number 7 (within-gene range 3–7): LINC01694, AL133493.1, AL133493.2, PCBP3, AL133492.1, PCBP3-AS1, AJ011931.2, AJ011931.1, AJ239328.1, AJ011932.1, COL6A1, AP001476.1, AP001476.3, AP001476.2, PSMA6P3, AP001471.1, COL6A2.
- chr22:28,883,572–31,134,697, 100 genes, copy number 10 (within-gene range 2–10) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,291. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
